MMRF case MMRF_1314 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/173ab77d-dd7b-4ef7-b2c3-7179a9170a7b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.0 years (22,635 days); ISS stage: II; Days to last known disease status: 1,522 days (4.2 years); Days to last follow up: 1,522 days (4.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 2): M Protein 3.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.058 mg/dL; Immunoglobulin G 50.9 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 9.9 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0.44 mg/dL.
- Day 67 (ECOG 2): M Protein 1.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.559 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 7.26 mmol/L.
- Day 178 (ECOG 0): M Protein 0.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.688 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.494 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 5.17 mmol/L.
- Day 255 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.68 mmol/L.
- Day 366 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.941 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.89 mmol/L.
- Day 444 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 9.81 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 6.44 mmol/L.
- Day 535 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.825 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.687 mg/dL; Immunoglobulin G 8.35 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 632 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 4.84 mmol/L.
- Day 731 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 9.35 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 5.56 mmol/L.
- Day 808 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 913 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 1,039 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.39 mmol/L.
- Day 1,101 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 8.1 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 1,199 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 1.73 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 6.7 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL.
- Day 1,262 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.874 mg/dL; Immunoglobulin G 5.88 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 4.9 mmol/L.
- Day 1,354 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 6.23 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 5.5 g/dL; Glucose 1.65 mmol/L.
- Day 1,430 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 5.5 g/dL; Glucose 4.95 mmol/L.
- Day 1,522: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 3.3 mmol/L.

Other clinical attributes
- Day -6: Weight: 72 kg; Height: 159 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lymphoma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1314_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1314_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
